Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A5FX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A5FX-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma w/ mixed
subtypes (cervix & endometrioid)

8255/3

Site: Endometrium C54.1

gnd 4/2/13

Date of Procedure:

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: SP: Right external iliac lymph nodes
- 3: SP: Right obturator lymph nodes
- 4: SP: Left external iliac lymph nodes
- 5: SP: Omentum

DIAGNOSIS:

1. SP: Uterus, cervix, bilateral fallopian tubes and ovaries:

Tumor Type:

High grade carcinoma, see note

Architectural Grade (For Endometrioid Types only):

III (>50% solid growth)

Nuclear Grade (For Endometrioid Types only):

Grade 3

FIGO Grade (For Endometrioid Types only):

Grade 3

Myometrial Invasion:

(>50%)

Measures 25mm in maximum depth

Myometrium thickness measures 26mm in the area of maximal tumor

invasion

Tumor extends to the subserosal surface.

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Identified

Endometrium:

Exhibits atrophy

Myometrium:

Unremarkable

Adnexa:

Right fallopian tube exhibits involvement by tumor

Left fallopian tube exhibits involvement by tumor

Ovaries are unremarkable

** Continued on next page **

[page 2 of 2]
[REDACTED]

NOTE: MORPHOLOGICALLY THE TUMOR SHOWS FEATURES OF BOTH SEROUS AND HIGH GRADE ENDOMETRIOID CARCINOMA. THE SLIDES FROM THE PREVIOUS CURETTAGE [REDACTED] ARE NOT AVAILABLE FOR REVIEW. THEY SHOWED A HIGH GRADE CARCINOMA THAT REPORTEDLY STAINED FOR ER, PR, CK7, AND P53 CONSISTENT WITH A SEROUS CARCINOMA. IMMUNOSTAINS PERFORMED ON THE CURRENT CASE SHOW THE TUMOR CELLS ARE DIFFUSELY POSITIVE FOR P16, WEAK AND FOCAL POSITIVE FOR P53 AND MODERATE TO STRONGLY POSITIVE FOR ER. CASE DISCUSSED AT CONSENSUS CONFERENCE.

2. LYMPH NODES, RIGHT EXTERNAL ILIAC; REGIONAL RESECTION:
- METASTATIC ADENOCARCINOMA INVOLVING TWO OF TWO LYMPH NODES (2/2).
3. LYMPH NODE, RIGHT OBTURATOR; BIOPSY:
- METASTATIC ADENOCARCINOMA INVOLVING ONE OF ONE LYMPH NODE (1/1).
4. LYMPH NODE, LEFT EXTERNAL ILIAC; BIOPSY:
- METASTATIC ADENOCARCINOMA INVOLVING ONE OF ONE LYMPH NODE (1/1).
5. OMENTUM; RESECTION:
- BENIGN OMENTUM.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]
*** Report Electronically Signed Out *** [REDACTED]

Gross Description:

[REDACTED]

Source: NCI Genomic Data Commons file 918d5b77-c47e-4e3d-ae00-3dcce79d9bd4 (TCGA-AP-A5FX.AF38CD86-2F5A-46A3-903A-81A8067F2456.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).